Somatic mutation profile of tumor specimen 0D9DR0 from CCDI case PBBINV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,347 days).
Specimen 0D9DR0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cd8ff93-2b08-4736-8de2-a381c8c7558e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9DR1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5ae457c-e251-4b79-95f3-bc895ed289e1

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.175C>G p.P59A (on ENST00000377970; = p.P74A on NM_002467.6) | Missense Mutation (SNP) | VAF 133/266 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs121918685, COSV52367409, COSV52367643, COSV52370791; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP2A13 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 345/796 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57840487; called by muse, mutect2, varscan2
- KAT8 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 275/553 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54898873; called by muse, mutect2, varscan2
- SIGLEC9 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 154/382 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); catalogued as rs748170583; called by muse, mutect2, varscan2
- ACOT8 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 47/695 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM171A2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FUOM | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 195/383 reads (51%) | called by muse, mutect2, varscan2
- MYOT | c.1411T>A p.L471M | Missense Mutation (SNP) | VAF 210/502 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NEO1 | c.1054_1055insT p.A352Vfs*10 | Frame Shift Ins (INS) | VAF 33/140 reads (24%) | called by mutect2, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99987084; called by muse, varscan2
- KLK2 | c.630+32G>T | Intron (SNP) | VAF 97/193 reads (50%) | catalogued as COSV57571161; called by muse, mutect2, varscan2
- MUC19 | c.325-39A>G | Intron (SNP) | VAF 14/104 reads (13%) | catalogued as rs1344620976; called by muse, mutect2
- NNT | c.1444+93A>G | Intron (SNP) | VAF 4/47 reads (9%) | catalogued as rs1410930887; called by muse, mutect2
- SSPOP | n.4999G>A | RNA (SNP) | VAF 33/211 reads (16%) | called by muse, mutect2, varscan2
